Somatic mutation profile of tumor specimen TCGA-D3-A2JN-06A (aliquot TCGA-D3-A2JN-06A-11D-A196-08) from TCGA case TCGA-D3-A2JN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 46.9 years (17,128 days).
Specimen TCGA-D3-A2JN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f94fb582-5efa-4377-8144-d44a1f2f5588.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A2JN-10A (Blood Derived Normal), aliquot TCGA-D3-A2JN-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa19ce0d-d188-4d83-baae-f0074c74aec2

The open-access MAF lists 385 somatic variants for this specimen: 265 protein-altering or splice-affecting, 116 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 233, Silent 116, Nonsense Mutation 18, Splice Site 5, Splice Region 4, RNA 3, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.9175C>T p.R3059C | Missense Mutation (SNP) | VAF 234/619 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs146377316, CM127717, COSV51947017; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ITGB3 | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs121918450, CM973033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.2084T>G p.L695R | Missense Mutation (SNP) | VAF 9/98 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62018756; called by muse, mutect2, varscan2
- ABCA5 | c.4715C>T p.P1572L | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs930791779, COSV67019021; called by muse, varscan2
- ABCA6 | c.3733C>T p.P1245S | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV52644653; called by muse, mutect2, varscan2
- ABCC1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 59/295 reads (20%) | catalogued as COSV60689282, COSV60693796; called by muse, mutect2, varscan2
- ABI3 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56801425; called by muse, mutect2, varscan2
- ACOXL | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as rs1203462539, COSV67735979; called by muse, mutect2, varscan2
- ACP6 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782213484, COSV65076746; called by muse, mutect2, varscan2
- ADAM32 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65953616; called by muse, mutect2, varscan2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2
- ADAM7 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV51536680, COSV51546498; called by muse, mutect2, varscan2
- ADAMTS6 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV66857214; called by muse, mutect2, varscan2
- ADCY8 | c.2884C>T p.H962Y | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as COSV53926689; called by muse, mutect2, varscan2
- ADH1B | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1353041149, COSV59298672; called by muse, mutect2, varscan2
- ADRA2B | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV69788312; called by muse, mutect2, varscan2
- ALMS1 | c.9878C>T p.S3293L | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52510001; called by muse, mutect2, varscan2
- ANK1 | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV55895497; called by muse, mutect2, varscan2
- APCDD1L | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100954052; called by muse, mutect2, varscan2
- ARMC12 | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as COSV55361666; called by muse, mutect2, varscan2
- ASL | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV59189442; called by muse, varscan2
- ASXL3 | c.4372G>A p.G1458R | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.312); catalogued as COSV52479065; called by muse, mutect2, varscan2
- ATP1A3 | c.1600G>A p.D534N (on ENST00000545399 / NM_001256214.2; = p.D521N on NM_152296.5) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV57491181; called by muse, mutect2, varscan2
- AXIN1 | c.2521C>T p.R841* | Nonsense Mutation (SNP) | VAF 28/120 reads (23%) | catalogued as rs370661416, COSV51993019; called by muse, mutect2, varscan2
- BCAR3 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769965474, COSV53077285; called by muse, mutect2, varscan2
- BCLAF3 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as COSV61415002; called by muse, mutect2, varscan2
- BDP1 | c.7612T>A p.L2538I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV62434618; called by muse, mutect2, varscan2
- BET1L | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs774346665, COSV57316244; called by mutect2, varscan2
- BIRC6 | c.2902G>A p.G968R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as COSV70205719; called by muse, mutect2
- BTK | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV58123631; called by muse, varscan2
- C1orf112 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV53682665; called by mutect2, varscan2
- C2CD6 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs765291829, COSV53800470; called by muse, mutect2, varscan2
- CACNB4 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV52394138; called by muse, mutect2, varscan2
- CAPN13 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs201525970, COSV54432486; called by muse, mutect2, varscan2
- CCDC148 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs770563296, COSV51770341; called by muse, mutect2, varscan2
- CD22 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV50067731; called by muse, mutect2, varscan2
- CDCA7 | c.311C>T p.S104F (on ENST00000347703 / NM_145810.3; = p.S183F on NM_031942.5) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV60721786; called by muse, mutect2, varscan2
- CDH5 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58519902; called by mutect2, varscan2
- CDH7 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV59893344, COSV59894401; called by muse, mutect2, varscan2
- CEP250 | c.4582C>T p.L1528F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.775); catalogued as COSV61174262; called by muse, mutect2, varscan2
- CHRNB4 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146608683, COSV55717226; called by muse, mutect2, varscan2
- CLEC2B | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | catalogued as rs762516896, COSV57308620; called by muse, mutect2, varscan2
- COL11A1 | c.486G>A p.G162= | Splice Region (SNP) | VAF 18/43 reads (42%) | catalogued as COSV62183926; called by muse, mutect2, varscan2
- COL14A1 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1162292969, COSV52867995; called by muse, varscan2
- COL22A1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV100280026; called by muse, mutect2, varscan2
- COL7A1 | c.5870G>A p.R1957Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.887); catalogued as rs1340588200, CM056317, COSV100096347, COSV100097265; called by mutect2, varscan2
- CR1 | c.6056G>A p.G2019E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65463080; called by muse, mutect2, varscan2
- CRB1 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV66330452; called by muse, mutect2, varscan2
- CSMD1 | c.8842G>A p.E2948K (on ENST00000520002; = p.E2947K on NM_033225.6) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV59381329; called by muse, mutect2, varscan2
- CSMD1 | c.8479C>T p.H2827Y (on ENST00000520002; = p.H2826Y on NM_033225.6) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.589); catalogued as rs370712015, COSV100145416, COSV59371592; called by muse, mutect2, varscan2
- CTNNB1 | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100846421; called by muse, varscan2
- CTNNB1 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100846422; called by muse, varscan2
- CYFIP2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.292); catalogued as COSV59050320; called by muse, mutect2, varscan2
- DARS2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53409034, COSV99508543; called by muse, mutect2, varscan2
- DDIAS | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as COSV61273243; called by muse, mutect2, varscan2
- DENND1C | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV57568974; called by muse, mutect2, varscan2
- DENND2A | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52058762; called by muse, mutect2, varscan2
- DHX57 | c.3303G>A p.W1101* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV54891118; called by muse, mutect2, varscan2
- DLG2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs145869624, COSV65873565; called by muse, mutect2, varscan2
- DMBX1 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); catalogued as rs142474862; called by muse, mutect2, varscan2
- DNAH10 | c.2389G>A p.E797K (on ENST00000409039; = p.E736K on NM_207437.3) | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.043); catalogued as COSV69001260; called by muse, mutect2, varscan2
- DNAH3 | c.8137G>A p.E2713K | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as COSV54515634; called by muse, mutect2, varscan2
- DNAH7 | c.9325G>A p.G3109R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56785272; called by muse, mutect2, varscan2
- DNAJC28 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1289914002, COSV58722151; called by muse, mutect2, varscan2
- DNPH1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99335847; called by muse, mutect2, varscan2
- DPYS | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60913563; called by muse, mutect2, varscan2
- DUSP26 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV56362440; called by muse, mutect2, varscan2
- EBF1 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV58194683; called by muse, mutect2, varscan2
- EDEM2 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65713670; called by muse, mutect2, varscan2
- EEF1E1 | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV65676084; called by muse, mutect2, varscan2
- EGFLAM | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59316817; called by muse, mutect2, varscan2
- ENPP3 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781156968, COSV62952931; called by mutect2, varscan2
- EPPIN | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs915255610, COSV60549148; called by muse, mutect2, varscan2
- F11R | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs149683377; called by muse, mutect2, varscan2
- F13A1 | c.2050A>T p.I684F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53567261; called by muse, mutect2, varscan2
- F2R | c.167G>A p.W56* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV59930146; called by muse, mutect2, varscan2
- FAM47C | c.2860G>A p.D954N | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63730291; called by muse, mutect2, varscan2
- FBXO42 | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs748281060, COSV65046929; called by muse, mutect2, varscan2
- FDX2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58533926; called by muse, mutect2, varscan2
- FIBIN | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59413508; called by muse, mutect2, varscan2
- FILIP1L | c.2627G>A p.G876E (on ENST00000354552 / NM_182909.3; = p.G636E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1197919343, COSV58765591; called by muse, mutect2, varscan2
- FLG2 | c.4198G>A p.G1400R | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761363545, COSV66173157; called by muse, mutect2, varscan2
- FLNC | c.3485G>A p.G1162E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57964684; called by muse, mutect2, varscan2
- FSTL5 | c.1747C>T p.H583Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1431638068, COSV60202352; called by muse, mutect2, varscan2
- GALNT13 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs779773642, COSV101223058, COSV67219169; called by muse, mutect2, varscan2
- GALR1 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55319068; called by muse, mutect2, varscan2
- GDAP1L1 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV61158848; called by mutect2, varscan2
- GDF2 | c.898C>G p.H300D | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1242016714; called by muse, mutect2, varscan2
- GFRAL | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61231832, COSV61231991; called by muse, varscan2
- GLI3 | c.2103G>A p.M701I | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV67894740; called by muse, mutect2, varscan2
- GPR142 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV59520436; called by mutect2, varscan2
- GPR18 | c.790T>C p.Y264H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as COSV61621516; called by muse, mutect2, varscan2
- GRIA1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs138865459, COSV53620211, COSV53623950; called by muse, varscan2
- GRM8 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV58867051; called by muse, mutect2, varscan2
- GTF3C1 | c.253T>G p.L85V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV55191477; called by muse, mutect2, varscan2
- HAL | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs952037997, COSV54116549; called by muse, mutect2, varscan2
- HES2 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV64705397; called by muse, mutect2, varscan2
- HTR1E | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as rs749518023, COSV100541258, COSV59507135; called by mutect2, varscan2
- IGHV4-31 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as rs766061846; called by muse, mutect2, varscan2
- IGKV2D-28 | c.350T>A p.L117Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV101494565; called by mutect2, varscan2
- IL1RAPL1 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56300159; called by muse, mutect2, varscan2
- ILDR2 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.604); catalogued as COSV54835329; called by muse, mutect2, varscan2
- IPPK | c.637-1G>C p.X213_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | catalogued as COSV55336275; called by muse, mutect2, varscan2
- ITGA8 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100958610, COSV65235701; called by mutect2, varscan2
- JAG2 | c.2547T>G p.Y849* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV59313010; called by muse, mutect2, varscan2
- JPH3 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs773282602, COSV52473843; called by mutect2, varscan2
- KCNH2 | c.3289G>A p.V1097I | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs199473030, COSV51220194; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- KCNJ5 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57971025; called by muse, mutect2, varscan2
- KDM7A | c.1639-1G>A p.X547_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | catalogued as COSV50095934; called by muse, mutect2, varscan2
- KIF1A | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV57501345; called by muse, mutect2, varscan2
- KIF4B | c.3029C>T p.T1010I | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1347120072, COSV70531280; called by muse, mutect2, varscan2
- KLHL4 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100910082, COSV64140665; called by muse, mutect2, varscan2
- KLHL4 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100910083; called by muse, mutect2, varscan2
- KNDC1 | c.4372G>A p.E1458K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58845983; called by muse, mutect2, varscan2
- KRT13 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV55841434; called by muse, mutect2, varscan2
- KRT36 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs967611020, COSV60204731; called by muse, mutect2, varscan2
- KRT79 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.741); catalogued as COSV57942168; called by muse, mutect2, varscan2
- KRTAP5-10 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.946); catalogued as COSV100924156; called by muse, mutect2, varscan2
- KY | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV71018664; called by muse, varscan2
- LAMB4 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV52730778; called by muse, mutect2, varscan2
- LRRC27 | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV59811771; called by muse, mutect2, varscan2
- LRRC56 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1407027234, COSV54246959; called by muse, mutect2, varscan2
- LRRIQ1 | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs577819664, COSV67827478; called by muse, mutect2, varscan2
- LTBP2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs146027819; called by muse, mutect2, varscan2
- MAGEC1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV53581303; called by muse, mutect2, varscan2
- MAN1C1 | c.1650G>A p.L550= | Splice Region (SNP) | VAF 12/55 reads (22%) | catalogued as COSV56048579; called by muse, mutect2, varscan2
- MAN2B2 | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as rs749799442, COSV53456722; called by muse, mutect2, varscan2
- MATR3 | c.1465G>C p.D489H | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV63079929; called by muse, mutect2, varscan2
- MBD6 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV63076388; called by muse, mutect2, varscan2
- MET | c.2986G>A p.V996I | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.393); catalogued as rs773447798, COSV59268837; called by muse, mutect2, varscan2
- MLXIPL | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57667342; called by muse, mutect2, varscan2
- MMP8 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779683730, COSV99368750; called by muse, mutect2, varscan2
- MORC1 | c.1530G>A p.W510* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV51730858; called by muse, mutect2, varscan2
- MRPS18C | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV55027904; called by muse, mutect2
- MSANTD1 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV70873355; called by muse, mutect2, varscan2
- MSH6 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as rs876659659, COSV99316674; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSH6 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99316675; called by muse, mutect2, varscan2
- MUC16 | c.39586G>A p.E13196K | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.828); catalogued as COSV66691089; called by muse, mutect2, varscan2
- MUC16 | c.35126C>T p.S11709F | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs867582847, COSV67448609; called by muse, mutect2, varscan2
- MUC16 | c.6514G>A p.A2172T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as rs1222502710, COSV67492381; called by muse, mutect2, varscan2
- MUSK | c.273C>G p.D91E | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.028); catalogued as rs1238167797, COSV51896569; called by muse, mutect2, varscan2
- MYL6B | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 59/246 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.378); catalogued as COSV52879684; called by muse, mutect2, varscan2
- MYLK | c.2936C>T p.P979L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs368229473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEO1 | c.1520C>T p.T507I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV56078083; called by muse, mutect2, varscan2
- NEXMIF | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV50100848, COSV99280382; called by muse, mutect2, varscan2
- NOL4 | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52361583; called by muse, mutect2, varscan2
- NUP210L | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs755939781, COSV55149735; called by muse, mutect2, varscan2
- NXPE4 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs1288745483, COSV64943433; called by muse, mutect2, varscan2
- OR10J1 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV71129652; called by muse, mutect2, varscan2
- OR10R2 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs138574952; called by muse, mutect2, varscan2
- OR2T10 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100393783; called by muse, mutect2, varscan2
- OR5H15 | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760449535, COSV62948986; called by muse, mutect2, varscan2
- OR6C2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59516913; called by muse, mutect2, varscan2
- OR6C6 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV64456246; called by muse, mutect2, varscan2
- OR6C76 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60389640; called by muse, mutect2, varscan2
- OR7G3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV59641039; called by muse, mutect2
- OSBPL3 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV57662350; called by muse, mutect2, varscan2
- OTOGL | c.1012C>T p.P338S (on ENST00000547103; = p.P329S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV72007472; called by muse, mutect2, varscan2
- OTOGL | c.3937C>T p.Q1313* (on ENST00000547103; = p.Q1304* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as rs907660131, COSV72007474; called by muse, mutect2, varscan2
- OTOP2 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs767497383, COSV58883679; called by mutect2, varscan2
- P2RX2 | c.697G>A p.D233N (on ENST00000343948 / NM_170683.4; = p.D161N on NM_012226.5) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1335122722, COSV57673653; called by muse, mutect2, varscan2
- P4HA3 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs770160749, COSV59043961; called by muse, mutect2, varscan2
- PADI4 | c.789dup p.L264Afs*52 | Frame Shift Ins (INS) | VAF 10/94 reads (11%) | catalogued as rs1557564854; called by mutect2, pindel, varscan2
- PAPPA2 | c.5053C>T p.P1685S | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.063); catalogued as rs778397336, COSV62811150; called by muse, varscan2
- PAX7 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.13); catalogued as rs900671673, COSV64752764; called by muse, mutect2, varscan2
- PBXIP1 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV63777693; called by mutect2, varscan2
- PCDH1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as rs1366429431, COSV54619225; called by muse, mutect2, varscan2
- PCDHA2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV65364567; called by muse, mutect2, varscan2
- PCDHAC1 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as COSV53868726; called by muse, mutect2, varscan2
- PCDHB3 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV50631131; called by muse, mutect2, varscan2
- PCNA | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64770800; called by muse, mutect2, varscan2
- PCYT2 | c.675C>T p.F225= | Splice Region (SNP) | VAF 7/42 reads (17%) | catalogued as COSV58712624; called by muse, mutect2, varscan2
- PGD | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54623094; called by muse, mutect2, varscan2
- PLCH1 | c.3374G>A p.G1125E (on ENST00000340059 / NM_001130960.2; = p.G1117E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV58209930; called by muse, mutect2, varscan2
- PMEPA1 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs1262955627, COSV55696362; called by muse, mutect2
- POTEM | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 66/483 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV69152726; called by muse, varscan2
- PPFIBP1 | c.1648G>A p.E550K (on ENST00000318304 / NM_177444.3; = p.E544K on NM_003622.4) | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs761302459, COSV57298477; called by muse, mutect2, varscan2
- PPP1R9A | c.2427G>A p.R809= | Splice Region (SNP) | VAF 9/82 reads (11%) | catalogued as COSV56910167; called by muse, mutect2
- PPP2R5A | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54819371; called by muse, mutect2, varscan2
- PTAFR | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59538297; called by muse, mutect2, varscan2
- PTPRT | c.1518G>A p.W506* | Nonsense Mutation (SNP) | VAF 48/226 reads (21%) | catalogued as COSV61962207; called by muse, mutect2, varscan2
- RADIL | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV101271419, COSV68203492; called by muse, mutect2
- RAPGEFL1 | c.1679G>A p.S560N | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV52864980; called by muse, mutect2, varscan2
- REEP2 | c.33-2A>G p.X11_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | catalogued as COSV54735887; called by muse, mutect2, varscan2
- RFESD | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.866); catalogued as COSV57225045; called by muse, mutect2, varscan2
- RGS22 | c.3658G>A p.E1220K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1473796566, COSV62667452; called by muse, mutect2
- RIOK1 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs865953300, COSV53573495; called by muse, mutect2
- RIPK2 | c.606A>C p.Q202H | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55135059; called by muse, mutect2
- RIPPLY3 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV61566983; called by muse, mutect2, varscan2
- ROCK2 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV55084529; called by muse, mutect2, varscan2
- RPTN | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 261/722 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60168589; called by muse, mutect2, varscan2
- RTN4 | c.3013G>A p.V1005I | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV58273757; called by muse, mutect2, varscan2
- RUSC2 | c.2911C>T p.P971S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100770822; called by muse, mutect2, varscan2
- RUSC2 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100770824; called by muse, mutect2, varscan2
- RYR2 | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs762057307, COSV63687064; called by mutect2, varscan2
- RYR3 | c.9445C>T p.P3149S (on ENST00000389232; = p.P3150S on NM_001036.6) | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as rs1359482829, COSV66807989; called by muse, mutect2, varscan2
- S100PBP | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1488810064, COSV63140646; called by muse, mutect2, varscan2
- SAMSN1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV53477444; called by muse, mutect2, varscan2
- SCGB1D4 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.628); catalogued as COSV62204450; called by muse, mutect2, varscan2
- SCN5A | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.757); catalogued as rs1429845416, COSV60068119; called by muse, mutect2, varscan2
- SCN9A | c.3353G>A p.R1118K (on ENST00000303354; = p.R1107K on NM_002977.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57623475; called by muse, mutect2
- SDC3 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59580704; called by muse, mutect2, varscan2
- SEMG1 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.773); catalogued as COSV54872454, COSV99725453; called by muse, mutect2, varscan2
- SETX | c.5909C>T p.S1970L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756752105, COSV56394402; called by muse, mutect2, varscan2
- SHBG | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs770459741, COSV52646498, COSV52646529; called by mutect2, varscan2
- SLAMF6 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV63588189; called by muse, varscan2
- SLC12A1 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV66799644; called by mutect2, varscan2
- SMARCAL1 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV61923559; called by muse, mutect2, varscan2
- SMARCE1 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 22/58 reads (38%) | catalogued as COSV52861806; called by muse, mutect2, varscan2
- SMC4 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as rs200043543, COSV100644109, COSV61004756; called by mutect2, varscan2
- SPAG16 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59091646; called by muse, mutect2, varscan2
- SPHKAP | c.4321G>A p.G1441R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV60893603; called by muse, mutect2, varscan2
- SS18L1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV59213598; called by muse, mutect2, varscan2
- STAT4 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61832269; called by muse, mutect2, varscan2
- STMN2 | c.312A>T p.K104N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV55222480; called by muse, mutect2, varscan2
- STMN4 | c.145G>T p.D49Y (on ENST00000265770 / NM_001283054.2; = p.D76Y on NM_030795.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV56110248, COSV99741224; called by muse, mutect2, varscan2
- TESK1 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99427583; called by muse, mutect2, varscan2
- TEX11 | c.924G>A p.M308I (on ENST00000344304; = p.M293I on NM_031276.3) | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60234487; called by muse, mutect2, varscan2
- TIMD4 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 126/489 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV50860121, COSV99192690; called by muse, mutect2, varscan2
- TMPRSS13 | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70627817; called by muse, mutect2, varscan2
- TNS3 | c.3008C>T p.S1003F | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV60795551, COSV60799147; called by muse, mutect2, varscan2
- TRIM40 | c.763C>T p.P255S (on ENST00000376724; = p.P226S on NM_138700.4) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV57157713; called by muse, mutect2, varscan2
- TRIM55 | c.719A>C p.K240T | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52550664; called by muse, mutect2, varscan2
- TTC13 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV100792935, COSV100792990, COSV64169145; called by muse, mutect2, varscan2
- TTC13 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs1202605771, COSV64168315; called by muse, mutect2, varscan2
- TTC37 | c.1151A>G p.N384S | Missense Mutation (SNP) | VAF 76/285 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV62456840; called by muse, mutect2, varscan2
- TTN | c.22264C>T p.R7422* (on ENST00000591111; = p.R6495* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs372250586, COSV59981639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.11543G>A p.G3848D (on ENST00000591111; = p.G3802D on NM_003319.4) | Missense Mutation (SNP) | VAF 29/131 reads (22%) | catalogued as rs1560912775, COSV100624582; called by muse, mutect2, varscan2
- TTN | c.7859G>A p.G2620E (on ENST00000591111; = p.G2574E on NM_003319.4) | Missense Mutation (SNP) | VAF 18/98 reads (18%) | PolyPhen probably damaging (1); catalogued as COSV100628758, COSV60339354; called by muse, mutect2, varscan2
- TUBA3C | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as rs754429286, COSV101313846, COSV68029603; called by muse, mutect2, varscan2
- TUBGCP5 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs574203342; called by muse, mutect2, varscan2
- TUBGCP6 | c.1490C>T p.T497I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); catalogued as rs765274070, COSV50583663; called by mutect2, varscan2
- UGT1A1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV100530724; called by muse, mutect2, varscan2
- URB2 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV51043192; called by muse, mutect2, varscan2
- VPS13B | c.5651T>C p.V1884A | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV62156591; called by muse, mutect2, varscan2
- VPS33A | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs577299919, COSV57358830; called by muse, mutect2, varscan2
- XKR6 | c.1200G>A p.W400* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV58659591; called by muse, mutect2, varscan2
- XRN1 | c.4889C>T p.P1630L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.347); catalogued as COSV53818044; called by muse, varscan2
- YEATS2 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100528181; called by muse, mutect2, varscan2
- YTHDC2 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs758300367, COSV50736507; called by muse, mutect2, varscan2
- ZBTB9 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV67702232; called by muse, mutect2, varscan2
- ZDBF2 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100985293; called by muse, mutect2, varscan2
- ZFHX4 | c.3280C>T p.L1094F | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs201918452; called by muse, mutect2, varscan2
- ZFPM2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs752577785, COSV68278632; called by muse, mutect2, varscan2
- ZNF114 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs775398198, COSV59945439; called by muse, mutect2, varscan2
- ZNF114 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV100252135; called by muse, mutect2, varscan2
- ZNF236 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | catalogued as COSV53484625, COSV53494039; called by muse, varscan2
- ZNF28 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as rs745591883, COSV60423169; called by muse, mutect2, varscan2
- ZNF341 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV61011173; called by muse, mutect2, varscan2
- ZNF354B | c.930G>C p.R310S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as COSV59367424; called by muse, mutect2, varscan2
- ZNF449 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868942697, COSV59348091; called by muse, mutect2, varscan2
- ZNF536 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762293077, COSV62832222; called by muse, mutect2, varscan2
- ZNF670 | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV63609000; called by muse, mutect2, varscan2
- ZNF699 | c.946T>G p.F316V | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58027039; called by muse, mutect2, varscan2
- ZNF813 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1453279458, COSV101124859, COSV101124970; called by muse, mutect2, varscan2
- ZSWIM2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.417); catalogued as COSV54574967; called by muse, mutect2, varscan2
- CLTC | c.1947+4_1947+20del p.X649_splice | Splice Site (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel
- COL6A6 | c.3826_3828del p.L1276del | In Frame Del (DEL) | VAF 33/292 reads (11%) | called by mutect2, varscan2
- FGF10 | c.251_252del p.S84Ffs*9 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by pindel, varscan2
- HUWE1 | c.10643C>T p.P3548L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- NCOA4 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- NLK | c.539_540delinsT p.K180Ifs*7 | Frame Shift Del (DEL) | VAF 36/121 reads (30%) | called by pindel, varscan2*
- PRAMEF15 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 65/509 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPTE | c.1574G>A p.R525K (on ENST00000618007 / NM_199261.4; = p.R507K on NM_199259.4) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACOXL | c.858G>A p.R286= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV101095635; called by muse, mutect2, varscan2
- ADAM18 | c.369C>T p.I123= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV55854992; called by muse, mutect2, varscan2
- ADGRB2 | c.126C>T p.A42= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1477059290, COSV99926740; called by muse, mutect2, varscan2
- ADRB2 | c.783T>C p.S261= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV60006240; called by muse, mutect2, varscan2
- AGO1 | c.141C>T p.I47= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs1337673800, COSV64596503; called by muse, varscan2
- ALDH1L1 | c.1779A>C p.T593= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs1467965811, COSV56419196; called by muse, mutect2, varscan2
- ALYREF | c.717G>A p.R239= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs765953765, COSV58669145; called by muse, mutect2, varscan2
- AMPD2 | c.132C>T p.A44= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1321683862, COSV99858038; called by muse, mutect2, varscan2
- APCDD1L | c.1152C>T p.A384= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100954051, COSV64486561; called by muse, mutect2, varscan2
- ARHGAP33 | c.1161C>T p.S387= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV50161370, COSV99138757; called by muse, mutect2, varscan2
- ATG2B | c.2352C>T p.F784= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs962334401, COSV63425511; called by mutect2, varscan2
- ATRN | c.1749C>T p.A583= | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as COSV53534244; called by muse, mutect2, varscan2
- C12orf43 | c.732C>T p.A244= | Silent (SNP) | VAF 203/847 reads (24%) | catalogued as rs1394218307, COSV56568490; called by muse, mutect2, varscan2
- C7 | c.372G>A p.R124= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs761808980, COSV57474110; called by muse, mutect2, varscan2
- C7orf33 | c.357C>T p.G119= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV61024003; called by muse, mutect2, varscan2
- CACNB4 | c.1488C>T p.Y496= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99139073; called by muse, mutect2, varscan2
- CDH9 | c.981G>C p.G327= | Silent (SNP) | VAF 69/180 reads (38%) | catalogued as COSV50412225, COSV50441075; called by muse, mutect2, varscan2
- CNNM2 | c.1359C>G p.L453= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV63995598, COSV63996429; called by muse, mutect2, varscan2
- COL20A1 | c.153G>A p.G51= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV58927063; called by muse, mutect2, varscan2
- COL7A1 | c.5871G>A p.R1957= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs780714666, COSV100097260; called by muse, mutect2, varscan2
- CPO | c.156C>T p.P52= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs764380322, COSV55941512; called by muse, mutect2, varscan2
- DGCR8 | c.2193C>T p.I731= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV52814990; called by muse, mutect2, varscan2
- DLG5 | c.5157C>T p.L1719= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV64949933; called by muse, mutect2, varscan2
- DLGAP2 | c.2274G>A p.V758= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV70103823; called by muse, mutect2, varscan2
- DNAH10 | c.7662C>T p.I2554= (on ENST00000409039; = p.I2493= on NM_207437.3) | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV69001263; called by muse, mutect2, varscan2
- DNAH11 | c.10977G>A p.A3659= | Silent (SNP) | VAF 36/112 reads (32%) | catalogued as rs778096489, COSV60977851; called by muse, mutect2, varscan2
- DNAH5 | c.5316G>A p.T1772= | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as rs1476390725, COSV54204064; called by muse, mutect2, varscan2
- DNPH1 | c.321G>A p.R107= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs762785467, COSV99335850; called by muse, mutect2, varscan2
- DOCK10 | c.1075C>T p.L359= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV51427536; called by muse, mutect2
- DOCK2 | c.5175G>A p.R1725= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV56987251; called by muse, mutect2, varscan2
- DSG2 | c.873G>A p.T291= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs760706353, COSV55201666; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYM | c.39A>G p.K13= | Silent (SNP) | VAF 34/132 reads (26%) | catalogued as COSV53992744; called by muse, mutect2, varscan2
- EBF2 | c.675G>A p.L225= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV68780540; called by muse, mutect2, varscan2
- ECM2 | c.858G>A p.E286= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100755822, COSV60742883; called by muse, mutect2, varscan2
- EHD1 | c.942C>T p.L314= | Silent (SNP) | VAF 22/163 reads (13%) | catalogued as COSV57736706; called by muse, mutect2, varscan2
- EOLA1 | c.91C>T p.L31= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV63734353; called by muse, mutect2, varscan2
- FAM71F2 | c.195G>A p.G65= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV66352443; called by muse, mutect2, varscan2
- FGF9 | c.420C>T p.F140= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs765041263, COSV101210939, COSV66644065; called by mutect2, varscan2
- FOXE1 | c.261C>T p.F87= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1340808410, COSV64301006; called by muse, mutect2
- GDF10 | c.687G>A p.E229= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1555207540; called by muse, mutect2, varscan2
- GJA8 | c.129C>T p.F43= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs267598000, COSV53787764; called by mutect2, varscan2
- GNPDA2 | c.579G>A p.V193= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV54948463; called by muse, mutect2, varscan2
- GRIA1 | c.2160C>T p.S720= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs1390099560, COSV53602775; called by muse, mutect2
- HRC | c.1032G>A p.R344= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs1247780136, COSV53258766; called by muse, mutect2, varscan2
- IGKV1-12 | c.348C>T p.F116= | Silent (SNP) | VAF 78/554 reads (14%) | called by muse, mutect2, varscan2
- IL7R | c.894C>T p.F298= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV57405582; called by muse, mutect2, varscan2
- IQCF1 | c.600C>T p.P200= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV58823859; called by muse, mutect2, varscan2
- IQCG | c.417C>T p.F139= | Silent (SNP) | VAF 86/398 reads (22%) | catalogued as rs766841659, COSV54566194; called by muse, mutect2, varscan2
- KCNA10 | c.501C>T p.S167= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs757659529, COSV63905298; called by muse, mutect2, varscan2
- KDM3B | c.2076C>T p.L692= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100069043, COSV58695171; called by muse, mutect2, varscan2
- KDM5A | c.3450C>T p.A1150= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as COSV66996307; called by muse, mutect2, varscan2
- KIAA1549 | c.2505T>C p.G835= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV54327777; called by muse, mutect2, varscan2
- KIF1B | c.3465C>T p.L1155= (on ENST00000377086 / NM_001365952.1; = p.L1109= on NM_015074.3) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV55815854; called by muse, mutect2, varscan2
- LHCGR | c.2028C>T p.S676= | Silent (SNP) | VAF 51/142 reads (36%) | catalogued as rs866421674, COSV54302896; called by muse, mutect2, varscan2
- LHFPL4 | c.468G>A p.R156= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV55004854; called by muse, mutect2, varscan2
- LILRB1 | c.333G>A p.Q111= (on ENST00000427581; = p.Q75= on NM_006669.6) | Silent (SNP) | VAF 14/229 reads (6%) | called by muse, mutect2
- LOXL4 | c.1548C>T p.S516= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as COSV53259256; called by muse, mutect2, varscan2
- LRRC3B | c.738G>A p.Q246= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV67522658; called by muse, mutect2, varscan2
- LSM11 | c.501G>A p.V167= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs758516954, COSV53849222; called by muse, mutect2, varscan2
- MAP3K10 | c.2709C>T p.S903= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV53425286; called by muse, mutect2, varscan2
- MAP3K13 | c.1110C>T p.L370= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as COSV53997311; called by muse, mutect2, varscan2
- MMP8 | c.699C>T p.A233= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99368747; called by muse, mutect2, varscan2
- MTHFD1 | c.2583C>T p.P861= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99387212; called by muse, mutect2, varscan2
- NEB | c.10632G>A p.P3544= | Silent (SNP) | VAF 64/235 reads (27%) | catalogued as rs200043736; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NEK10 | c.2727G>A p.S909= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs764123485, COSV55355950; called by muse, mutect2, varscan2
- OR10A2 | c.687C>G p.S229= | Silent (SNP) | VAF 59/175 reads (34%) | catalogued as COSV56300515; called by muse, mutect2, varscan2
- OR10A7 | c.315C>T p.F105= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as COSV58278414, COSV58279549; called by muse, mutect2, varscan2
- OR1S1 | c.117C>T p.L39= | Silent (SNP) | VAF 14/157 reads (9%) | catalogued as COSV58706578; called by muse, mutect2
- OR2T10 | c.297C>T p.T99= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100393781; called by muse, mutect2, varscan2
- OR4L1 | c.435G>A p.A145= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs374852761, COSV59851227; called by muse, mutect2, varscan2
- OR6C4 | c.432C>T p.F144= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as COSV67793295; called by muse, mutect2, varscan2
- OTOGL | c.3357T>A p.I1119= (on ENST00000547103; = p.I1110= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/120 reads (22%) | catalogued as COSV72007473; called by muse, mutect2, varscan2
- P2RY14 | c.168C>T p.F56= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV56396615; called by muse, mutect2, varscan2
- PCDHGB6 | c.717C>T p.P239= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV54029567; called by muse, mutect2, varscan2
- PCNX3 | c.3732C>T p.F1244= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs781719158, COSV63134850; called by muse, mutect2, varscan2
- PGS1 | c.547C>T p.L183= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99428450; called by muse, mutect2, varscan2
- PLEKHG4B | c.3000G>A p.Q1000= (on ENST00000283426; = p.Q1356= on NM_052909.5) | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV52054923; called by muse, mutect2, varscan2
- POLR3E | c.1065C>T p.F355= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs749194794, COSV55401645; called by muse, mutect2, varscan2
- POM121 | c.3141C>T p.F1047= (on ENST00000434423; = p.F782= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs781964052, COSV57513089, COSV57523713; called by muse, mutect2, varscan2
- PRAMEF12 | c.72C>T p.A24= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs765294432, COSV63216657; called by muse, mutect2, varscan2
- PTPRT | c.354G>A p.G118= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV62018780; called by muse, varscan2
- RHBG | c.774G>A p.L258= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV54809805; called by muse, mutect2, varscan2
- RPS6KA2 | c.354C>T p.H118= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV55830111; called by muse, mutect2, varscan2
- RYR3 | c.8025G>A p.L2675= (on ENST00000389232; = p.L2676= on NM_001036.6) | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV101214507, COSV66807981; called by muse, mutect2, varscan2
- SH2B1 | c.1236G>A p.L412= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV59466856; called by muse, mutect2, varscan2
- SHPRH | c.1906C>T p.L636= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV51617577; called by muse, varscan2
- SLC6A11 | c.615G>A p.E205= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs1214757143, COSV54398906; called by muse, mutect2, varscan2
- SMC4 | c.1668G>A p.K556= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV61003247, COSV61007909; called by muse, mutect2, varscan2
- SMYD3 | c.330C>T p.F110= (on ENST00000490107 / NM_001375962.1; = p.F51= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as COSV66455162; called by muse, mutect2, varscan2
- SOWAHA | c.1497G>T p.S499= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV66332771; called by muse, mutect2, varscan2
- SPATA31E1 | c.3216C>A p.T1072= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV57795118; called by muse, mutect2, varscan2
- SPEG | c.9582C>T p.F3194= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV56679379; called by muse, mutect2, varscan2
- SPHKAP | c.1041C>T p.S347= | Silent (SNP) | VAF 42/129 reads (33%) | catalogued as COSV60880095; called by muse, mutect2, varscan2
- SRL | c.123C>T p.T41= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV101281362, COSV68424538; called by muse, mutect2, varscan2
- ST3GAL1 | c.711C>T p.I237= | Silent (SNP) | VAF 71/136 reads (52%) | catalogued as COSV60616520; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3471C>T p.F1157= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs1463454589, COSV59138072; called by muse, mutect2, varscan2
- TENM1 | c.6696C>T p.G2232= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV64442697; called by muse, mutect2, varscan2
- TENM1 | c.681C>A p.P227= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as COSV64440629; called by muse, mutect2, varscan2
- TESK1 | c.654G>A p.V218= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99427582; called by muse, mutect2, varscan2
- TET3 | c.4125C>T p.L1375= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1244481718, COSV69644864, COSV69645545; called by muse, mutect2
- TICRR | c.5376C>T p.D1792= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV51546826; called by muse, mutect2, varscan2
- TM9SF4 | c.606C>T p.Y202= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV54111443; called by muse, varscan2
- TMEM132B | c.294C>T p.P98= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as rs747653473, COSV54769284; called by muse, mutect2, varscan2
- TRIM32 | c.1770C>T p.I590= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs776504480, COSV57816775; called by muse, mutect2, varscan2
- TUBGCP5 | c.2716C>T p.L906= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- UBR4 | c.15129T>A p.L5043= | Silent (SNP) | VAF 39/226 reads (17%) | catalogued as COSV64399094; called by muse, mutect2, varscan2
- UGT3A1 | c.456C>T p.F152= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV57103242; called by muse, mutect2, varscan2
- UNC13A | c.1491G>A p.R497= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV53209907; called by muse, varscan2
- VAV1 | c.234C>T p.F78= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as COSV100409198, COSV58378081; called by muse, mutect2, varscan2
- VPS13D | c.6150G>A p.G2050= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV50681577; called by muse, mutect2, varscan2
- WNT8B | c.18T>C p.P6= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV59326807; called by muse, mutect2, varscan2
- YTHDF2 | c.1353G>A p.G451= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV65724160; called by muse, mutect2, varscan2
- ZBTB21 | c.2484C>T p.S828= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV60405740; called by muse, mutect2, varscan2
- ZFPM2 | c.3390C>T p.N1130= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1332156664, COSV65875823; called by muse, mutect2
- ZMIZ2 | c.2310C>T p.T770= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV54810908; called by muse, mutect2, varscan2
- ZNF561 | c.294G>A p.L98= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV57177743, COSV57178433; called by muse, mutect2, varscan2
- MFSD12 | chr19:3542865 G>A | 3'Flank (SNP) | VAF 5/48 reads (10%) | catalogued as COSV61536759; called by muse, mutect2, varscan2
- MIR525 | n.62C>T | RNA (SNP) | VAF 14/57 reads (25%) | catalogued as rs959657314; called by muse, mutect2, varscan2
- SNORD114-2 | n.10G>A | RNA (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- XIST | n.7930C>T | RNA (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
